Somatic mutation profile of tumor specimen TARGET-40-PARGTM-01A (aliquot TARGET-40-PARGTM-01A-01D) from TARGET case TARGET-40-PARGTM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.2 years (5,925 days).
Specimen TARGET-40-PARGTM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d260971-579b-467f-9454-c9b30ac1a7c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARGTM-10A (Blood Derived Normal), aliquot TARGET-40-PARGTM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c6c5a4a-65d1-4b49-99dc-7147560c70f7

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 1 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Intron 4, 5'UTR 2, 3'UTR 2, Splice Region 1, Nonsense Mutation 1, RNA 1, Splice Site 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DBT | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768389398, CM104303; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- DGKG | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs368444168, COSV53975826; called by muse, mutect2, varscan2
- DNAH10 | c.5212C>G p.Q1738E (on ENST00000409039; = p.Q1677E on NM_207437.3) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV101292862; called by muse, mutect2, varscan2
- F8 | c.1963T>A p.Y655N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM055183; called by muse, mutect2, varscan2
- FETUB | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149523201, COSV54004743; called by muse, mutect2, varscan2
- GPR68 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs149975079; called by muse, mutect2, varscan2
- IQCE | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58079578; called by muse, mutect2
- KCNH8 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.362); catalogued as rs762973332; called by muse, mutect2, varscan2
- MUC17 | c.721G>T p.V241F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV60287203; called by muse, mutect2
- NLRP13 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as COSV61624061; called by muse, mutect2
- TNXB | c.5939C>T p.A1980V (on ENST00000647633; = p.A1733V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV64474796; called by muse, mutect2
- WDR5 | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs1235101906; called by muse, mutect2
- ABRA | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- ARMC2 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB2 | c.809A>G p.E270G | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- BCCIP | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.499); called by muse, mutect2
- COP1 | c.1562T>G p.F521C | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CPAMD8 | c.4246T>C p.S1416P (on ENST00000651564; = p.S1369P on NM_015692.5) | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2
- CPXCR1 | c.646A>G p.K216E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CRTC2 | c.256-4G>A | Splice Region (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- DDX24 | c.1990-2A>C p.X664_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- DUOXA2 | c.253A>C p.T85P | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- HCN4 | c.1663T>G p.Y555D | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IL1R1 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- LAMA4 | c.5038A>C p.S1680R (on ENST00000230538 / NM_001105206.3; = p.S1673R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MGA | c.2710del p.Q904Rfs*29 | Frame Shift Del (DEL) | VAF 79/217 reads (36%) | called by mutect2, pindel, varscan2
- MMEL1 | c.1996C>G p.Q666E | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OTOGL | c.4613T>G p.M1538R (on ENST00000547103; = p.M1529R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by mutect2, varscan2
- PI4KA | c.1322G>C p.C441S | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2
- PLEKHG5 | c.2029G>C p.E677Q (on ENST00000400915 / NM_001042663.3; = p.E640Q on NM_020631.6) | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- PPARA | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM12 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RADIL | c.2534A>T p.E845V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, varscan2
- RBM12B | c.2784G>C p.K928N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RFPL4A | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- TACR3 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF814 | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- KRTAP15-1 | c.117T>C p.N39= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- BSDC1 | c.-12C>T | 5'UTR (SNP) | VAF 7/138 reads (5%) | catalogued as rs967410626; called by muse, mutect2
- FRMPD3 | c.397-21A>G | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- IVNS1ABP | c.895+41A>G | Intron (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- ROMO1 | c.-14C>T | 5'UTR (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- SEZ6L | c.*1731A>G | 3'UTR (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- ST13P4 | n.1041C>A | RNA (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- STEAP3 | c.1185+2619C>A | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- TBRG4 | c.1567+46C>G | Intron (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- ZNF99 | c.*364G>A | 3'UTR (SNP) | VAF 10/25 reads (40%) | catalogued as rs556797516; called by muse, mutect2, varscan2
